Somatic mutation profile of tumor specimen TARGET-30-PARABJ-01A (aliquot TARGET-30-PARABJ-01A-01D) from TARGET case TARGET-30-PARABJ, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.8 years (661 days).
Specimen TARGET-30-PARABJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7511e790-0345-4819-90a0-addafef9459e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARABJ-10A (Blood Derived Normal), aliquot TARGET-30-PARABJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0888c7b-4270-40f8-a4bb-e11b588733b3

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD2 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV53968538, COSV53968683; called by muse, mutect2, varscan2
- CAMP | c.491dup p.L164Ffs*26 (on ENST00000296435; = p.L161Ffs*26 on NM_004345.5) | Frame Shift Ins (INS) | VAF 18/115 reads (16%) | catalogued as rs753541088; called by mutect2, pindel, varscan2
- CHRNA10 | c.857C>A p.A286D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51705455, COSV51707523; called by muse, mutect2
- DNAH11 | c.6134A>T p.K2045M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60963342; called by muse, mutect2, varscan2
- TDRD6 | c.5305C>T p.R1769C | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs369479623; called by muse, mutect2, varscan2
- CAT | c.171C>T p.F57= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV53811734; called by muse, mutect2, varscan2
- SCAF11 | c.2838A>G p.R946= | Silent (SNP) | VAF 19/138 reads (14%) | catalogued as rs763215381, COSV65477406; called by muse, mutect2, varscan2
